Somatic mutation profile of tumor specimen TCGA-L5-A4OI-01A (aliquot TCGA-L5-A4OI-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OI, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 79.9 years (29,190 days).
Specimen TCGA-L5-A4OI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a17cfd3b-d553-4c56-834e-80616ca0eb44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OI-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OI-11A-11D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ceeabfad-6e08-4bac-b9e5-14ce3fc4795f

The open-access MAF lists 1,975 somatic variants for this specimen: 1,526 protein-altering or splice-affecting, 413 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 983, Silent 413, Frame Shift Del 384, Frame Shift Ins 66, Nonsense Mutation 39, Splice Site 24, Intron 14, Splice Region 14, In Frame Del 14, RNA 8, 5'UTR 5, 5'Flank 5.

Variants (750 of 1,975; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- B2M | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CEP290 | c.3175del p.I1059* | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs62640570, CD073593; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTNS | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs113994207, CM992865, COSV50440436; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CWC27 | c.1002dup p.V335Sfs*13 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERCC6 | c.2287-2A>G p.X763_splice | Splice Site (SNP) | VAF 18/37 reads (49%) | catalogued as rs754978734, CS099990; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HAX1 | c.430dup p.V144Gfs*5 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs770288337; ClinVar: pathogenic; called by mutect2, varscan2
- ITGB4 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs121912462, CM981090, COSV52322436; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PPARG | c.556del p.S186Vfs*47 (on ENST00000287820 / NM_015869.5; = p.S156Vfs*47 on NM_005037.7) | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as rs587776687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 26/58 reads (45%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- RNF168 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as rs201915239, CM112023; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- SF3B4 | c.1060dup p.R354Pfs*132 | Frame Shift Ins (INS) | VAF 21/82 reads (26%) | catalogued as rs782357237; ClinVar: pathogenic; called by mutect2, varscan2
- SLC17A5 | c.349del p.Y117Mfs*17 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs772039085; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TMEM70 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as rs387907070, CM111396, COSV100383980; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WDR19 | c.641dup p.L214Ffs*5 | Frame Shift Ins (INS) | VAF 22/42 reads (52%) | catalogued as rs587777348; ClinVar: pathogenic; called by mutect2, varscan2
- AACS | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs772486562, COSV55540999; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 34/46 reads (74%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCA2 | c.4387G>A p.G1463R (on ENST00000614293; = p.G1433R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs1430950986, COSV99686818; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABHD14A-ACY1 | c.1396del p.R466Lfs*28 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as COSV68343820; called by mutect2, pindel, varscan2
- ABLIM1 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs148624929; called by muse, mutect2, varscan2
- AC008397.2 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs765962984; called by muse, mutect2, varscan2
- AC011448.1 | c.667del p.L223Sfs*2 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs1222818786; called by mutect2, pindel, varscan2
- AC090517.4 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as rs377486429; called by muse, mutect2, varscan2
- ACVR1B | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs754157211; called by muse, mutect2, varscan2
- ACVR1C | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs201171210, COSV54645922; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 56/74 reads (76%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778239614, COSV56646393, COSV56646868; called by muse, mutect2, varscan2
- ADAM22 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as rs778859953, COSV55981739; called by muse, mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 43/68 reads (63%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAMTS17 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs755767925, COSV51492016; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs760078676, COSV65900315; called by muse, mutect2, varscan2
- ADCY5 | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs762578500, COSV59201616; called by muse, mutect2, varscan2
- ADCY9 | c.3028G>A p.G1010R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53573573; called by muse, mutect2, varscan2
- ADGRB2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.496); catalogued as rs904940190, COSV57078691; called by muse, mutect2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | catalogued as rs764604854; called by pindel, varscan2
- ADGRF5 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs776153232, COSV51929887; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADGRL3 | c.2458G>T p.G820C (on ENST00000506720 / NM_001322402.2; = p.G752C on NM_015236.6) | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72231712; called by muse, mutect2
- ADM | c.530dup p.S178Efs*19 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs773405081; called by mutect2, varscan2
- ADRB1 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65167681; called by muse, mutect2, varscan2
- AFAP1 | c.128-1G>T p.X43_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100631949; called by muse, mutect2, varscan2
- AFMID | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs771105807, COSV59975387; called by muse, mutect2, varscan2
- AGBL1 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs373676885; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKNA | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746948550; called by muse, mutect2, varscan2
- AKR1B15 | c.814dup p.T272Nfs*29 | Frame Shift Ins (INS) | VAF 28/60 reads (47%) | catalogued as rs768391747; called by mutect2, varscan2
- AKR1E2 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368269250; called by muse, mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALDH1L2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51556883; called by muse, mutect2, varscan2
- ALDH4A1 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs149468487; called by muse, mutect2, varscan2
- ALDOA | c.77del p.P26Qfs*20 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs768781534; called by mutect2, pindel, varscan2
- ALPK2 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs752603625; called by muse, mutect2, varscan2
- AMER3 | c.611del p.P204Rfs*62 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as COSV100365971, COSV58465768; called by mutect2, pindel, varscan2
- ANKMY1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1243761323, COSV56038261; called by muse, mutect2, varscan2
- ANKRD11 | c.5540C>T p.S1847L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1294353692, COSV99968524; called by muse, mutect2, varscan2
- ANKRD11 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1450559184; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD35 | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs782724338, COSV62910890; called by muse, varscan2
- ANKRD50 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1317883312; called by muse, mutect2, varscan2
- AOC2 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200726584; called by muse, mutect2, varscan2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | catalogued as rs753324780, COSV52227333; called by mutect2, pindel, varscan2
- APBB1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1394180630; called by muse, mutect2, varscan2
- APH1B | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56013696, COSV56014386; called by muse, mutect2, varscan2
- APOBR | c.1247C>T p.P416L (on ENST00000431282; = p.P425L on NM_018690.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs965539423, COSV100112762; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 48/129 reads (37%) | catalogued as rs749401724; called by mutect2, varscan2
- APPL2 | c.1221dup p.Q408Tfs*18 | Frame Shift Ins (INS) | VAF 43/132 reads (33%) | catalogued as rs759930326; called by mutect2, varscan2
- ARFGEF1 | c.5227C>T p.R1743C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs758636963; called by muse, mutect2, varscan2
- ARHGEF18 | c.3160G>A p.G1054S (on ENST00000359920 / NM_001130955.2; = p.G950S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs567452162, COSV100149524, COSV60469136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARL2BP | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs150513555; called by muse, mutect2, varscan2
- ARMC5 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs202056991, COSV51657733; called by muse, mutect2, varscan2
- ARMH3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1301593069, COSV64233381; called by muse, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | catalogued as rs753865255; called by mutect2, varscan2
- ARVCF | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs375905723; called by muse, mutect2, varscan2
- ASTN1 | c.3797C>T p.A1266V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs934363990, COSV100706651, COSV62494925; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs746676748; called by mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs771531141; called by mutect2, varscan2
- ATG9A | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs763159203; called by muse, mutect2, varscan2
- ATMIN | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs752448184; called by muse, mutect2, varscan2
- ATP10B | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs374878756; called by muse, mutect2, varscan2
- ATP1A2 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV100768169; called by muse, mutect2
- ATP1A4 | c.411+1G>A p.X137_splice | Splice Site (SNP) | VAF 19/58 reads (33%) | catalogued as rs754150634, COSV63625985, COSV63627038; called by muse, mutect2, varscan2
- ATP2A1 | c.2230G>A p.V744I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as rs866421756, COSV100707138; called by muse, mutect2, varscan2
- ATP2B4 | c.2563G>A p.V855M | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs748977323; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139454557; called by muse, varscan2
- AXDND1 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.059); catalogued as rs778985705, COSV62639856; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs778012871; called by mutect2, pindel, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BAHCC1 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as rs782682025; called by muse, mutect2, varscan2
- BAHCC1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782505897; called by muse, mutect2
- BATF | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV54375401; called by muse, mutect2, varscan2
- BAZ2A | c.5492G>A p.R1831Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1160934682; called by muse, mutect2, varscan2
- BBS10 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV53889418; called by muse, mutect2, varscan2
- BCL2L2 | c.570del p.F190Lfs*55 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs763348226; called by mutect2, pindel, varscan2
- BDP1 | c.938dup p.L313Ffs*9 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | catalogued as rs752427670; called by mutect2, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BIRC6 | c.10997G>A p.R3666H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.921); catalogued as rs759663407, COSV101428247; called by muse, mutect2, varscan2
- BLNK | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs781845656, COSV56410328; called by muse, mutect2, varscan2
- BMP2 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1345011787; called by muse, mutect2, varscan2
- BRCA2 | c.370A>G p.M124V | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as CD104368; called by muse, mutect2, varscan2
- BRD4 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1368408404; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs751388819; called by mutect2, varscan2
- C12orf43 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV56568481, COSV99981970; called by muse, mutect2, varscan2
- C12orf66 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs763086764, COSV61324518; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 30/69 reads (43%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C3 | c.2670del p.K891Sfs*13 | Frame Shift Del (DEL) | VAF 36/101 reads (36%) | catalogued as rs750770711, COSV99837243; called by mutect2, pindel, varscan2
- C8A | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs200098041, COSV63483265; called by muse, varscan2
- CA10 | c.272dup p.R92Qfs*47 | Frame Shift Ins (INS) | VAF 27/61 reads (44%) | catalogued as rs1180449128; called by mutect2, pindel, varscan2
- CACNA1E | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373651535, COSV62386777; called by muse, mutect2, varscan2
- CACNA1E | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770435124, COSV62412751; called by muse, mutect2, varscan2
- CACNA1F | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV59904061; called by muse, mutect2, varscan2
- CACNA1H | c.441del p.F147Lfs*37 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | catalogued as rs868275022; called by mutect2, pindel, varscan2
- CACNA1S | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs146696298; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CACNG5 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs772824396, COSV50059067; called by muse, mutect2, varscan2
- CACNG5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141219015; called by muse, mutect2, varscan2
- CAMSAP3 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as COSV99350021; called by muse, mutect2, varscan2
- CAMTA1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs756787846, COSV57879540; called by muse, mutect2, varscan2
- CAMTA2 | c.2597dup p.A867Cfs*7 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN11 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs201179894; called by muse, mutect2, varscan2
- CARD9 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs1420017314; called by muse, mutect2, varscan2
- CARMIL3 | c.1883G>T p.R628L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV57726617; called by muse, mutect2, varscan2
- CBLC | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs377703099; called by muse, mutect2, varscan2
- CCDC136 | c.3174_3175del p.C1058Wfs*3 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs1562976837; called by pindel, varscan2
- CCDC142 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as rs773641936, COSV51780143; called by muse, mutect2, varscan2
- CCDC3 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs754059035, COSV66558962; called by muse, mutect2, varscan2
- CCDC33 | c.984del p.G329Afs*17 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as COSV58351549; called by mutect2, pindel, varscan2
- CCDC33 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs750144807, COSV51434570; called by muse, mutect2, varscan2
- CCDC40 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376363442; ClinVar: uncertain significance; called by muse, mutect2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC7 | c.3801G>A p.M1267I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.79); catalogued as rs750843554, COSV56536686; called by muse, mutect2, varscan2
- CCDC77 | c.135del p.E46Kfs*32 | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | catalogued as COSV53475781; called by mutect2, pindel, varscan2
- CCDC96 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs377449312; called by muse, mutect2, varscan2
- CCER1 | c.410del p.P137Qfs*30 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as COSV62646324; called by mutect2, varscan2
- CCR7 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs773362430; called by muse, varscan2
- CCSER1 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1332114208; called by muse, mutect2, varscan2
- CD46 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as rs1457827640; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC45 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.961); catalogued as rs369554602; called by muse, mutect2, varscan2
- CDCP2 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs1391233473; called by muse, mutect2, varscan2
- CDH20 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs1166288202; called by muse, mutect2
- CDK12 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71000304; called by muse, mutect2, varscan2
- CECR2 | c.3541A>G p.R1181G (on ENST00000342247 / NM_001290047.2; = p.R997G on NM_001290046.1) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs554572738; called by muse, mutect2, varscan2
- CEP131 | c.2884G>A p.E962K (on ENST00000269392 / NM_001319228.2; = p.E959K on NM_014984.4) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs755773021, COSV99487726; called by muse, mutect2, varscan2
- CERK | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761985697; called by muse, mutect2, varscan2
- CES5A | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1236939914; called by muse, mutect2, varscan2
- CFAP45 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as rs1557916345; called by muse, mutect2, varscan2
- CFAP46 | c.7214del p.P2405Lfs*5 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs1344439240; called by pindel, varscan2
- CHAT | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201479289, CM119375; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- CHAT | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746595362, COSV100341012, COSV60328546; called by muse, mutect2, varscan2
- CHRM3 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs145638222; called by muse, mutect2, varscan2
- CHRM3 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903730617, COSV55082398; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 21/40 reads (53%) | catalogued as rs751548647; called by mutect2, varscan2
- CLASRP | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.17); catalogued as rs1020929443, COSV55516250; called by muse, mutect2, varscan2
- CLN6 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.127); catalogued as rs374613712; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLP1 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1270735408, COSV57054379; called by muse, mutect2, varscan2
- CLVS1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs368485692; called by muse, mutect2, varscan2
- CNKSR1 | c.1535del p.P512Hfs*58 (on ENST00000374253 / NM_001297647.2; = p.P505Hfs*58 on NM_006314.3) | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as rs753922055; called by pindel, varscan2*
- CNKSR2 | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54267418; called by muse, mutect2, varscan2
- CNTN5 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777370237, COSV54297226, COSV54327473; called by muse, mutect2, varscan2
- CNTRL | c.6724C>T p.R2242C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs764668280, COSV53050420; called by muse, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL13A1 | c.1780G>A p.D594N (on ENST00000398978 / NM_001130103.2; = p.D522N on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as COSV62567696; called by muse, mutect2, varscan2
- COL14A1 | c.3524C>T p.S1175L | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as rs369127166; called by muse, mutect2, varscan2
- COL18A1 | c.2043G>A p.T681= (on ENST00000359759 / NM_130444.3; = p.T446= on NM_030582.4) | Splice Region (SNP) | VAF 12/43 reads (28%) | catalogued as rs527870177, COSV62705285; called by muse, mutect2, varscan2
- COL21A1 | c.758del p.K253Rfs*2 | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | catalogued as rs773380190; called by mutect2, pindel, varscan2
- COL3A1 | c.2590G>T p.G864C | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483764; called by muse, mutect2
- COL5A2 | c.3791C>T p.T1264M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.818); catalogued as rs762902468, COSV66407684; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COL9A1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1477827595; called by muse, mutect2, varscan2
- COPA | c.3088C>T p.R1030C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54101128; called by muse, mutect2, varscan2
- CPB1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766816862, COSV51573302; called by muse, mutect2, varscan2
- CPLX4 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs752019452, COSV55313481; called by muse, mutect2, varscan2
- CPNE9 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781590918; called by muse, mutect2, varscan2
- CPT1B | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs1423499725, COSV56416375; called by muse, mutect2, varscan2
- CR2 | c.592_595del p.S199Rfs*19 | Frame Shift Del (DEL) | VAF 34/127 reads (27%) | catalogued as rs868255776; called by mutect2, pindel, varscan2
- CRYAB | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs782206421, COSV57051877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF2RB | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as rs769513501; called by muse, mutect2, varscan2
- CSF3R | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58966049; called by muse, mutect2, varscan2
- CSMD2 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs775463572, COSV53879418; called by muse, mutect2, varscan2
- CSMD2 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as rs767425150, COSV53883241; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSRNP3 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 31/58 reads (53%) | catalogued as COSV58776980; called by muse, mutect2, varscan2
- CTC1 | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as rs758206104, COSV59852456; called by muse, mutect2, varscan2
- CTNNA2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.655); catalogued as rs760574291, COSV63559645, COSV63597945; called by muse, mutect2, varscan2
- CUBN | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs201958183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUBN | c.479del p.P160Hfs*23 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as COSV100910537; called by mutect2, pindel, varscan2
- CUL2 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs776824977, COSV101039039; called by muse, mutect2, varscan2
- CUX2 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747887990; called by muse, mutect2, varscan2
- CYP11B2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as rs202173105, COSV59995171; called by muse, mutect2, varscan2
- CYP24A1 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53776474; called by muse, mutect2, varscan2
- CYP46A1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs752278427, COSV55897107; called by muse, mutect2, varscan2
- CYP4Z1 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.716); catalogued as rs776044257; called by muse, mutect2, varscan2
- DAAM2 | c.2968C>T p.R990C (on ENST00000274867 / NM_001201427.2; = p.R989C on NM_015345.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs368619961, COSV51362996; called by muse, mutect2, varscan2
- DAPK1 | c.3822dup p.Y1275Vfs*64 | Frame Shift Ins (INS) | VAF 7/19 reads (37%) | catalogued as rs779681511; called by mutect2, varscan2
- DCAF4 | c.271del p.L91* | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as COSV62320168; called by mutect2, pindel, varscan2
- DCAF6 | c.2065C>T p.R689W (on ENST00000312263 / NM_001349778.1; = p.R709W on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs773283748, COSV56579829; called by muse, varscan2
- DCAF8 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs368652723, COSV100470155; called by muse, mutect2, varscan2
- DCLK2 | c.2136G>C p.R712S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.026); catalogued as rs1333223286; called by muse, mutect2, varscan2
- DCP1A | c.28_30del p.E10del | In Frame Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs782348180; called by mutect2, pindel, varscan2
- DDR2 | c.2290T>C p.F764L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63374895; called by muse, mutect2, varscan2
- DDX59 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1335673753; called by muse, mutect2, varscan2
- DEDD2 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.297); catalogued as rs749103293, COSV60142319; called by muse, mutect2, varscan2
- DENND1B | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs573965743, COSV54145408; called by muse, mutect2, varscan2
- DENND4A | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563702022; called by muse, mutect2, varscan2
- DENND6B | c.1357dup p.Q453Pfs*9 | Frame Shift Ins (INS) | VAF 9/30 reads (30%) | catalogued as rs772127145; called by mutect2, varscan2
- DHX37 | c.2674C>T p.R892W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369049552; called by muse, mutect2, varscan2
- DLL1 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs779932154, COSV64537893; called by muse, mutect2, varscan2
- DMC1 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as rs1162366253; called by muse, mutect2, varscan2
- DNAH10 | c.3565G>T p.D1189Y (on ENST00000409039; = p.D1128Y on NM_207437.3) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV68988918; called by muse, mutect2, varscan2
- DNAH11 | c.10596G>T p.L3532F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV60943161; called by muse, mutect2, varscan2
- DNAH17 | c.5926G>A p.D1976N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763851473; called by muse, mutect2, varscan2
- DNAJC11 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.08); catalogued as rs375527993; called by mutect2, varscan2
- DNM2 | c.2155C>T p.R719W (on ENST00000355667 / NM_001005360.3; = p.R715W on NM_004945.3) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757334523, CM1511554, COSV99284101; called by muse, mutect2, varscan2
- DNMT3B | c.1359dup p.L454Afs*11 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | catalogued as rs756395138; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs1239294263; called by mutect2, pindel, varscan2
- DOK6 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as rs1417394627, COSV66927138; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs35482889; called by mutect2, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs748560644; called by mutect2, pindel, varscan2
- DSC2 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); catalogued as rs143413607, CM107154; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DSTYK | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs780479792, COSV65688734; called by muse, mutect2, varscan2
- DTL | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1328927692; called by muse, mutect2, varscan2
- DVL2 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as rs1400645935; called by muse, mutect2, varscan2
- DYNC1H1 | c.9232C>T p.R3078W | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794543; called by muse, mutect2, varscan2
- ECE1 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752979342, COSV51664096; called by muse, mutect2, varscan2
- ECEL1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV58813156; called by muse, mutect2, varscan2
- ECM1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461591997; called by muse, mutect2, varscan2
- ECSIT | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.125); catalogued as rs773846640; called by muse, mutect2, varscan2
- EDIL3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56918367, COSV99031181; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as rs536698371; called by muse, mutect2, varscan2
- EEF2 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58580116; called by muse, mutect2, varscan2
- EFHC2 | c.1314dup p.A439Cfs*10 | Frame Shift Ins (INS) | VAF 14/18 reads (78%) | catalogued as rs752671785; called by mutect2, varscan2
- EGFLAM | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as rs951136341, COSV59302576; called by muse, mutect2, varscan2
- EGLN2 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375774477; called by muse, varscan2
- EIF2A | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV56408721; called by muse, mutect2, varscan2
- EIF2AK4 | c.2447A>G p.Q816R | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs370476691; called by muse, mutect2, varscan2
- EIF2AK4 | c.4892del p.K1631Rfs*48 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as rs1400253542; called by mutect2, pindel, varscan2
- EIF4E | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV55187800; called by muse, mutect2, varscan2
- EIF4E1B | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765322594, COSV53782101; called by muse, mutect2, varscan2
- ELMO3 | c.1730G>A p.R577Q (on ENST00000652269; = p.R524Q on NM_024712.5) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs759674356; called by muse, mutect2, varscan2
- EMX2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV71294378; called by muse, mutect2, varscan2
- EPN1 | c.765G>A p.S255= (on ENST00000270460 / NM_001321263.1; = p.S230= on NM_013333.3) | Splice Region (SNP) | VAF 17/60 reads (28%) | catalogued as rs1195533986, COSV50036372; called by muse, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs755604942; called by pindel, varscan2
- EPS8L1 | c.2065G>A p.V689M (on ENST00000201647 / NM_133180.3; = p.V562M on NM_017729.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99136145; called by muse, mutect2, varscan2
- ERAL1 | c.788A>C p.K263T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV54740554, COSV99650519; called by muse, mutect2, varscan2
- ERBB2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54071878; called by muse, mutect2, varscan2
- ERBB4 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs774895831, COSV53590582; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERO1B | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs758392975, COSV59243725; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC4 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as rs1482943898; called by muse, mutect2, varscan2
- EXOSC10 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs763574577, COSV100442233; called by muse, mutect2, varscan2
- F2R | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs546007149; called by muse, mutect2, varscan2
- F8 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs146581224; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAAH | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs775398610, COSV54543985; called by muse, varscan2
- FAHD2A | c.842dup p.G282Rfs*17 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | catalogued as rs766589051; called by mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAHD2B | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1426534573, COSV55631488; called by muse, mutect2, varscan2
- FAM135B | c.3821C>A p.S1274Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52729690; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM166A | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61116387; called by muse, mutect2, varscan2
- FAM184A | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs757793663, COSV58857335; called by muse, mutect2, varscan2
- FAM241B | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758997308, COSV100958389; called by muse, mutect2, varscan2
- FAM71A | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs374912338; called by muse, mutect2, varscan2
- FAM83E | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs200129085; called by muse, mutect2, varscan2
- FAM83G | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs760541119, COSV100524669; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs746983128; called by mutect2, varscan2
- FARP1 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs772815989; called by muse, mutect2, varscan2
- FAT3 | c.8317C>T p.R2773C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs780613312, COSV53111551, COSV53127574; called by muse, mutect2, varscan2
- FBN3 | c.6436G>A p.G2146R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs752167961, COSV54457493; called by muse, mutect2, varscan2
- FBN3 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs149936210; called by muse, mutect2, varscan2
- FBXO46 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1364470397; called by muse, mutect2, varscan2
- FBXO6 | c.596A>G p.E199G | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.324); catalogued as rs745901399; called by muse, mutect2, varscan2
- FBXW5 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs561473224; called by muse, mutect2, varscan2
- FCRL3 | c.1412-2A>G p.X471_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV63839334; called by muse, mutect2, varscan2
- FEM1A | c.998del p.G333Afs*31 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | catalogued as COSV54163812; called by mutect2, pindel, varscan2
- FER1L6 | c.5468del p.K1823Sfs*48 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs1369383113; called by mutect2, pindel, varscan2
- FGA | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs199717989, CM071755, COSV57393571; called by muse, mutect2, varscan2
- FGF3 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782535318; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs144178676; called by mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGLA | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1553390682; called by muse, mutect2, varscan2
- FLACC1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs759419207, COSV53782788; called by muse, mutect2, varscan2
- FLYWCH1 | c.1133C>A p.P378Q (on ENST00000253928 / NM_001308068.2; = p.P377Q on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as rs375862744; called by muse, mutect2, varscan2
- FMN2 | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs1161570864, COSV100141975; called by muse, mutect2, varscan2
- FOCAD | c.4991C>T p.T1664M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755938108, COSV58103146; called by muse, mutect2, varscan2
- FOXD1 | c.102_104del p.E34del | In Frame Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs780101710; called by pindel, varscan2
- FOXP1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs751543308; called by muse, mutect2, varscan2
- FRAS1 | c.4814C>T p.A1605V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs749776166; called by muse, mutect2, varscan2
- FRAS1 | c.6287G>A p.R2096H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs774682680, COSV53639347; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs752538869; called by pindel, varscan2
- FRZB | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778534128; called by muse, mutect2, varscan2
- FTMT | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as rs753267058, COSV100360363; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- FXR1 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as rs199785386, COSV99976756; called by muse, mutect2, varscan2
- G2E3 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746122872, COSV52840270; called by muse, mutect2, varscan2
- GAL3ST1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0.019); catalogued as rs778200200; called by muse, mutect2
- GAL3ST2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs202108971, COSV51950164; called by muse, mutect2, varscan2
- GALNT10 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs375000619, COSV51730933; called by muse, mutect2, varscan2
- GALR1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1026231983, COSV55317434; called by muse, mutect2
- GBF1 | c.2332C>T p.R778* (on ENST00000369983 / NM_001377137.1; = p.R777* on NM_004193.3) | Nonsense Mutation (SNP) | VAF 52/113 reads (46%) | catalogued as rs1216081573, COSV64143855; called by muse, mutect2, varscan2
- GBF1 | c.4450G>A p.V1484M (on ENST00000369983 / NM_001377137.1; = p.V1483M on NM_004193.3) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as rs373502588, COSV64149913; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 54/147 reads (37%) | catalogued as rs548474277; called by mutect2, varscan2
- GDAP2 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146263543; called by muse, mutect2, varscan2
- GFPT2 | c.934A>G p.M312V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs781093292; called by muse, mutect2, varscan2
- GGNBP2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1374070000; called by muse, mutect2, varscan2
- GGT7 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs772474622; called by muse, mutect2, varscan2
- GIPC1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs564587407; called by muse, varscan2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GLI2 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); catalogued as rs200095340, COSV58034459; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLIS1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426949401, COSV56550901; called by muse, mutect2, varscan2
- GNB1L | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs138225912; called by muse, mutect2, varscan2
- GON4L | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.127); catalogued as rs933918427; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | catalogued as rs370114090; called by mutect2, varscan2
- GPALPP1 | c.969del p.K323Nfs*5 | Frame Shift Del (DEL) | VAF 12/124 reads (10%) | catalogued as rs1566086213; called by mutect2, pindel, varscan2
- GPR18 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs778649813, COSV100540543; called by muse, mutect2, varscan2
- GPR183 | c.962G>T p.R321M | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV63118100; called by muse, mutect2, varscan2
- GPR68 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs766671876; called by muse, mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs759103894; called by pindel, varscan2
- GPR89A | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs587615888; called by muse, mutect2, varscan2
- GPRC6A | c.2161C>A p.L721I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV59955209; called by muse, mutect2, varscan2
- GREB1 | c.3983G>A p.R1328Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.18); catalogued as rs777556736; called by muse, mutect2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 12/17 reads (71%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK3 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs142974275; called by muse, mutect2, varscan2
- GRIN2B | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200727145, COSV74205564, COSV74206077; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GUCY2C | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as rs762829348; called by muse, mutect2, varscan2
- HAPLN4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52269389; called by muse, mutect2, varscan2
- HCN1 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs772962018, COSV57526034; called by muse, mutect2, varscan2
- HDAC11 | c.291dup p.V98Rfs*70 | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | catalogued as rs754533859; called by mutect2, varscan2
- HEATR5A | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs758539397, COSV66341578; called by muse, mutect2, varscan2
- HEATR5B | c.6214del p.*2072Nfs*3 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | catalogued as rs1315552549, COSV51848615; called by mutect2, varscan2
- HELLS | c.1840del p.R614Efs*11 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs745837238; called by mutect2, varscan2
- HEPH | c.476dup p.S160Qfs*18 (on ENST00000343002; = p.S214Qfs*18 on NM_138737.5) | Frame Shift Ins (INS) | VAF 12/26 reads (46%) | catalogued as rs757816158; called by mutect2, pindel, varscan2
- HEPHL1 | c.3276C>T p.N1092= | Splice Region (SNP) | VAF 13/23 reads (57%) | catalogued as rs560509955, COSV100243839, COSV59889234; called by muse, mutect2, varscan2
- HIF1A | c.2068G>A p.V690M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs761548161, COSV60188698; called by muse, mutect2, varscan2
- HIPK4 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.202); catalogued as rs777721110, COSV52520339; called by muse, mutect2, varscan2
- HIVEP3 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1438448679; called by muse, mutect2
- HIVEP3 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.928); catalogued as rs984979732; called by muse, mutect2, varscan2
- HMOX1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs903006597, COSV99330584; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1940del p.G647Efs*268 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs1451726686; called by mutect2, pindel, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 41/103 reads (40%) | catalogued as rs755016625; called by mutect2, varscan2
- HOOK3 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV56887644; called by muse, mutect2, varscan2
- HP1BP3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs142958960; called by muse, mutect2, varscan2
- HPCAL4 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs750128709, COSV65716160; called by muse, mutect2, varscan2
- HPCAL4 | c.69C>A p.S23R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV65716060; called by muse, mutect2
- HRH4 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs149820026; called by muse, mutect2, varscan2
- HRNR | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 46/128 reads (36%) | catalogued as rs142288299; called by muse, mutect2, varscan2
- HSD17B4 | c.264_266del p.R90del (on ENST00000414835 / NM_001199291.3; = p.R65del on NM_000414.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs770940142; called by pindel, varscan2
- HSD17B4 | c.1901C>T p.S634F (on ENST00000414835 / NM_001199291.3; = p.S609F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs772944749, COSV99819581; called by muse, mutect2, varscan2
- HSPA2 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as COSV99904656; called by muse, mutect2, varscan2
- HTT | c.3742G>A p.A1248T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs376975573; called by muse, mutect2, varscan2
- HUWE1 | c.7634G>A p.R2545H | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs782597093, COSV53340431; called by muse, mutect2, varscan2
- HVCN1 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs755674445, COSV99657396; called by muse, mutect2, varscan2
- HYAL4 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs1481760488, COSV56140538; called by muse, mutect2, varscan2
- IDO1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761098064, COSV99503702; called by muse, mutect2, varscan2
- IDO2 | c.824A>G p.H275R (on ENST00000389060; = p.H288R on NM_194294.2) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1236549130, COSV58424247; called by muse, varscan2
- IFI44 | c.1332del p.K444Nfs*17 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as rs1309076306; called by mutect2, pindel, varscan2
- IFT172 | c.2584del p.D862Tfs*42 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as COSV53131688; called by mutect2, pindel, varscan2
- IGF2 | c.271G>A p.G91R (on ENST00000434045 / NM_001127598.3; = p.G35R on NM_000612.6) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100324167, COSV56101858; called by muse, mutect2, varscan2
- IGHV3-23 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.082); catalogued as rs781860463; called by muse, mutect2, varscan2
- IGLV3-10 | c.147dup p.Y50Ifs*19 | Frame Shift Ins (INS) | VAF 17/47 reads (36%) | catalogued as rs776773283; called by mutect2, varscan2
- IGLV3-16 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs775615687; called by muse, mutect2, varscan2
- IGSF10 | c.1786C>A p.H596N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV99176661; called by muse, mutect2, varscan2
- IL17RD | c.2051C>T p.T684M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1382761196, COSV99577840; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INCENP | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.698); catalogued as rs200902528; called by muse, mutect2, varscan2
- INO80 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs758451886; called by muse, mutect2, varscan2
- INO80D | c.1540del p.M514Wfs*5 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as COSV68960008; called by mutect2, pindel, varscan2
- INPP5B | c.907C>T p.R303C (on ENST00000373023; = p.R223C on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs752264648, COSV65960958; called by muse, mutect2, varscan2
- INTS10 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs754588177, COSV67604519; called by muse, mutect2, varscan2
- IRS1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV59333403; called by muse, varscan2
- IRS2 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.133); catalogued as COSV65477543; called by muse, mutect2, varscan2
- IRX1 | c.1247T>A p.V416D | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.54); PolyPhen benign (0.047); catalogued as COSV100116307; called by muse, mutect2, varscan2
- ISM1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs753984610, COSV99339807; called by muse, mutect2, varscan2
- ISM1 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1395688045, COSV52607357; called by muse, mutect2, varscan2
- ITGAD | c.2118del p.I707Ffs*6 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as COSV66758525; called by mutect2, pindel, varscan2
- JADE1 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV56908714; called by muse, mutect2, varscan2
- JKAMP | c.460G>A p.V154I (on ENST00000554271 / NM_001284201.1; = p.V140I on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs755619284; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs749731829, COSV59822983; called by muse, mutect2, varscan2
- JSRP1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs747006364; called by muse, mutect2, varscan2
- KALRN | c.7219C>T p.R2407C (on ENST00000360013 / NM_001024660.4; = p.R710C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747606269, COSV52261167; called by muse, mutect2, varscan2
- KANK1 | c.3897C>T p.N1299= | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as rs755985194; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs752059864; called by mutect2, varscan2
- KCND3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs374337721; called by muse, mutect2, varscan2
- KCNH1 | c.2078G>A p.R693Q (on ENST00000271751 / NM_172362.3; = p.R666Q on NM_002238.4) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV55111110; called by muse, mutect2, varscan2
- KCNJ10 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514673, CM105040, COSV100927976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNT1 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV53680937; called by muse, mutect2, varscan2
- KCNV1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99819084; called by muse, mutect2, varscan2
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 19/36 reads (53%) | catalogued as rs759860142; called by mutect2, pindel, varscan2
- KCTD8 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 14/141 reads (10%) | catalogued as rs1220125757, COSV100760248; called by muse, mutect2
- KDM6B | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs767579418; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs752375544, COSV54318481; called by mutect2, pindel, varscan2
- KIAA2026 | c.5626del p.I1876* | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | catalogued as rs1372228416; called by mutect2, pindel, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | catalogued as rs749990720; called by mutect2, varscan2
- KIDINS220 | c.3242del p.P1081Rfs*48 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as COSV56750269; called by mutect2, pindel, varscan2
- KIF14 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs147387069; called by muse, mutect2, varscan2
- KIF21A | c.2675T>C p.L892S (on ENST00000361418 / NM_001378440.1; = p.L879S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs1443528519; called by muse, mutect2, varscan2
- KIF21B | c.3740G>A p.R1247H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs777757543, COSV59757144; called by muse, mutect2, varscan2
- KIF21B | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs376964063, COSV59754147; called by muse, mutect2, varscan2
- KIF3B | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs1018945730; called by muse, mutect2, varscan2
- KIF6 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749063566, COSV54666093; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs777890702; called by mutect2, pindel, varscan2
- KIRREL3 | c.1732C>T p.R578* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV69385769, COSV69386698; called by muse, mutect2, varscan2
- KITLG | c.659T>C p.L220S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs372594912; called by muse, mutect2, varscan2
- KLC2 | c.1700del p.G567Afs*11 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs772643711; called by mutect2, pindel, varscan2
- KLF15 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs557895851; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as COSV52930337; called by mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KMT2B | c.7946G>A p.R2649H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53073765; called by muse, mutect2, varscan2
- KMT5A | c.849C>T p.C283= | Splice Region (SNP) | VAF 75/157 reads (48%) | catalogued as rs752726590, COSV57864064; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 58/72 reads (81%) | catalogued as rs764099275; called by mutect2, varscan2
- KRT10 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462577911; called by muse, mutect2
- KRT33A | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs768092751, COSV50375186; called by muse, mutect2, varscan2
- KRT9 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs762726903, COSV55853216; called by muse, mutect2
- KRTAP4-3 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs752492912, COSV66940842; called by muse, mutect2, varscan2
- KRTAP6-1 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 76/203 reads (37%) | PolyPhen probably damaging (0.943); catalogued as COSV58168367; called by muse, mutect2, varscan2
- KRTAP9-2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66647023; called by muse, mutect2, varscan2
- L2HGDH | c.906G>A p.P302= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as rs144701373; called by muse, mutect2, varscan2
- LAMA1 | c.7543G>A p.A2515T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as rs553037503; called by muse, mutect2, varscan2
- LAMA1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150637419; called by muse, mutect2, varscan2
- LAMA5 | c.8827G>A p.G2943S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.881); catalogued as rs1368466743; called by muse, mutect2, varscan2
- LAMA5 | c.6658C>T p.R2220W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs112553935; called by muse, mutect2
- LAMB4 | c.3161C>T p.P1054L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs757343921; called by muse, mutect2, varscan2
- LAMC3 | c.2336dup p.Q781Pfs*7 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | catalogued as rs765163533; called by mutect2, pindel, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as COSV65473126, COSV65473260; called by mutect2, varscan2
- LGR6 | c.1756G>A p.V586M (on ENST00000367278 / NM_001017403.1; = p.V534M on NM_021636.3) | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs143028945; called by muse, mutect2, varscan2
- LILRA4 | c.1424del p.P475Qfs*69 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs758325116, COSV52491499; called by mutect2, pindel, varscan2
- LILRB5 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs376519844; called by muse, mutect2, varscan2
- LMLN | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198458826; called by muse, mutect2, varscan2
- LRG1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs374325546; called by muse, mutect2, varscan2
- LRIG2 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs780877821, COSV100743828; called by muse, mutect2, varscan2
- LRP10 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760967418, COSV62077686; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 54/119 reads (45%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP1B | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV67228656; called by muse, mutect2, varscan2
- LRRC24 | c.719del p.P240Rfs*52 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as COSV99467335; called by mutect2, pindel, varscan2
- LRRC37A2 | c.4960T>C p.Y1654H | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs772353375; called by muse, mutect2, varscan2
- LRRC37B | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs145638325; called by muse, mutect2, varscan2
- LRRC66 | c.2551G>A p.V851I | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773799470; called by muse, mutect2, varscan2
- LRRC8D | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61580857; called by muse, mutect2, varscan2
- LRRK1 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs753053998, COSV52617087; called by muse, mutect2, varscan2
- LTBP3 | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs1318622119, COSV100099599; called by muse, mutect2, varscan2
- LYAR | c.62A>G p.H21R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761005527; called by muse, mutect2, varscan2
- LYN | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1563526105; called by muse, mutect2, varscan2
- LYST | c.7690G>A p.A2564T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs759733310, COSV67703467; called by muse, mutect2, varscan2
- LZTR1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768361273, COSV53150648; called by muse, mutect2, varscan2
- MAN1A2 | c.1860G>T p.E620D | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100741010; called by muse, mutect2
- MAP1B | c.4990C>T p.R1664* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV57105491; called by muse, mutect2
- MAP3K5 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs760179645; called by muse, mutect2, varscan2
- MAP3K6 | c.2735G>A p.S912N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.328); catalogued as rs772079491; called by muse, mutect2, varscan2
- MAP3K7 | c.1297G>A p.G433R (on ENST00000369329 / NM_145331.3; = p.G406R on NM_003188.4) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774760752, COSV65224058; called by muse, mutect2, varscan2
- MAPK10 | c.127G>A p.A43T (on ENST00000359221 / NM_001351625.2; = p.A81T on NM_002753.5) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1416981784, COSV60387180; called by muse, varscan2
- MAPK8IP3 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as rs1012235118, COSV51722969; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3605del p.G1202Afs*38 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as COSV51600001; called by mutect2, pindel, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs777328830; called by mutect2, varscan2
- MARK1 | c.1730G>T p.R577L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV65065893, COSV65067743; called by muse, mutect2
- MARK4 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as rs1039550856, COSV53464813; called by muse, mutect2, varscan2
- MARS2 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1337059237; called by muse, mutect2, varscan2
- MBTPS1 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100597829; called by muse, mutect2
- MCM2 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs763364817; called by muse, mutect2, varscan2
- MCOLN1 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV51174021; called by muse, mutect2, varscan2
- MCPH1 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs575272870, COSV60919250; called by muse, mutect2, varscan2
- MDGA2 | c.1264C>A p.R422S (on ENST00000399232 / NM_001113498.2; = p.R124S on NM_182830.4) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV62092387; called by muse, mutect2, varscan2
- MDH1B | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.27); catalogued as rs766638320, COSV65590726; called by muse, mutect2, varscan2
- MEAF6 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs889481618, COSV56163127; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 28/93 reads (30%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED13L | c.5708G>A p.R1903H | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1039753021, COSV56132224; called by muse, mutect2, varscan2
- MEGF6 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as rs1017264793, COSV99620650; called by muse, mutect2, varscan2
- METTL15 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145080229; called by muse, mutect2, varscan2
- MFN2 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.781); catalogued as CM113099; called by muse, mutect2, varscan2
- MFSD13A | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1267309215; called by muse, mutect2, varscan2
- MGAT5B | c.1483G>A p.V495M (on ENST00000569840 / NM_001199172.2; = p.V493M on NM_144677.3) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200878515; called by muse, mutect2, varscan2
- MICAL3 | c.4033C>T p.R1345C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs143851801; called by muse, mutect2, varscan2
- MICAL3 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV52906532; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MKI67 | c.6122C>T p.A2041V | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772060315; called by muse, mutect2, varscan2
- MNS1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs529820032, COSV53067878; called by muse, mutect2, varscan2
- MOB3A | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV63865362; called by muse, mutect2, varscan2
- MORN1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs146451358; called by muse, mutect2, varscan2
- MOXD1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV63455404; called by muse, mutect2, varscan2
- MPP6 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99757896; called by muse, mutect2
- MRPL32 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV56239753; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MSH4 | c.1149del p.F383Lfs*20 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs776677874; called by mutect2, pindel, varscan2
- MSR1 | c.818-1G>T p.X273_splice | Splice Site (SNP) | VAF 21/70 reads (30%) | catalogued as rs772978107, CS061306, COSV50541813; called by muse, mutect2, varscan2
- MSX1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485301859, CM1513798; called by muse, mutect2, varscan2
- MTMR7 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376725869; called by muse, mutect2, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 23/114 reads (20%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MTX1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs768575109, COSV57427018; called by muse, mutect2, varscan2
- MUC2 | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); catalogued as rs556795222; called by muse, mutect2, varscan2
- MYEF2 | c.1394G>A p.S465N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.063); catalogued as rs200959924; called by muse, mutect2, varscan2
- MYH11 | c.1100C>A p.T367K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1026635988; called by muse, mutect2
- MYH14 | c.4097G>A p.R1366H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs553162373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH4 | c.3071T>C p.L1024P | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150138598; called by muse, mutect2, varscan2
- MYL10 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV56207637, COSV56207670; called by muse, mutect2, varscan2
- MYO15A | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.874); catalogued as rs750391522, COSV99232021; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 38/73 reads (52%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO18A | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs373443144, COSV62866359; called by muse, mutect2, varscan2
- MYO18B | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs375068756; called by muse, mutect2, varscan2
- MYO18B | c.6733A>G p.S2245G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1407529944; called by muse, mutect2, varscan2
- MYO18B | c.7630G>A p.E2544K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs760339139, COSV59130770; called by muse, mutect2, varscan2
- MYO5C | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777427902; called by muse, mutect2, varscan2
- MYO6 | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781458857, COSV64120230; called by muse, varscan2
- MYOM2 | c.2186T>C p.L729P | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50768730; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 28/52 reads (54%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- NAA25 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs776147529, COSV99927499; called by muse, mutect2, varscan2
- NACC2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs1192910616; called by muse, mutect2, varscan2
- NALCN | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.633); catalogued as rs149203278, COSV51927610; called by muse, varscan2
- NARS1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs181716261, COSV56876757; called by muse, mutect2, varscan2
- NAV2 | c.185T>G p.V62G | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs771552408, COSV62322994; called by muse, mutect2, varscan2
- NBEA | c.6308C>T p.T2103M | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as rs756245795, COSV59777018; called by muse, mutect2, varscan2
- NBEAL2 | c.3850T>A p.W1284R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52760928; called by muse, mutect2, varscan2
- NBPF10 | c.11065del p.R3689Efs*32 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs781875736; called by mutect2, pindel, varscan2
- NCAPD2 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as rs770092608, COSV100217509; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 33/70 reads (47%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCAPG2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs1331986042, COSV99317691; called by muse, mutect2, varscan2
- NCBP1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.427); catalogued as rs199742053; called by muse, mutect2, varscan2
- NDST4 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs369719779, COSV52129411; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs747914168; called by mutect2, varscan2
- NECTIN1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763840300; called by muse, mutect2, varscan2
- NETO1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100197997; called by muse, mutect2, varscan2
- NEUROG2 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as rs747836494, COSV57638062; called by muse, mutect2, varscan2
- NINJ2 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs774958514; called by muse, mutect2, varscan2
- NLGN4Y | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.836); catalogued as COSV59295615; called by muse, mutect2, varscan2
- NLRP12 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as COSV60753819; called by muse, mutect2, varscan2
- NMT2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.217); catalogued as COSV104427619; called by muse, mutect2, varscan2
- NOBOX | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as rs780611966, COSV56193927; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL8 | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as rs753203498; called by muse, mutect2, varscan2
- NOP14 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as rs148438590; called by muse, varscan2
- NPAP1 | c.788del p.P263Lfs*19 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs1367265166; called by mutect2, varscan2
- NPBWR1 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563548077, COSV58695375; called by muse, mutect2, varscan2
- NPEPL1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1430790801, COSV100622442; called by muse, mutect2, varscan2
- NPR2 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs1263762640; called by muse, mutect2, varscan2
- NPR3 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1326088788; called by muse, mutect2, varscan2
- NRDC | c.3115G>A p.G1039R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543997; called by muse, mutect2, varscan2
- NSD1 | c.6649del p.E2217Rfs*77 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as CM1211957; called by mutect2, pindel, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTRK3 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as rs750565995, COSV100448310, COSV58113168, COSV58150381; called by muse, mutect2, varscan2
- NUP210 | c.5332G>A p.A1778T | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs750230647; called by muse, mutect2, varscan2
- NYNRIN | c.4081G>A p.G1361S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as rs375921086, COSV101230664; called by muse, mutect2, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs781171419; called by mutect2, pindel, varscan2
- OBSCN | c.22264G>A p.V7422M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs375115158; called by muse, mutect2, varscan2
- OCIAD2 | c.444C>A p.D148E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56716488; called by muse, mutect2, varscan2
- OGN | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.506); catalogued as rs753494407; called by muse, mutect2, varscan2
- OPRK1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201421010; called by muse, mutect2, varscan2
- OR4M1 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1420763428; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 21/35 reads (60%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR51A7 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs781626934; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs755413956; called by mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 36/47 reads (77%) | catalogued as rs746200712; called by mutect2, varscan2
- OR6C76 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 43/95 reads (45%) | catalogued as rs545177147; called by muse, mutect2, varscan2
- OR7C2 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs139042107, COSV50182289; called by muse, mutect2, varscan2
- OR8G1 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as rs753993339; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 30/76 reads (39%) | catalogued as rs780916980; called by mutect2, varscan2
- OTX1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56995259; called by muse, mutect2, varscan2
- PAN2 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs140591449; called by muse, mutect2, varscan2
- PANK4 | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1158864629; called by muse, mutect2, varscan2
- PAPLN | c.1201G>A p.V401M (on ENST00000554301; = p.V374M on NM_173462.4) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as rs892962722; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs758945932; called by mutect2, varscan2
- PBRM1 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56305288; called by muse, mutect2, varscan2
- PCARE | c.2966del p.P989Lfs*46 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | catalogued as rs770881706; called by mutect2, pindel, varscan2
- PCDH1 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs753105427, COSV54615871; called by muse, mutect2, varscan2
- PCDH11X | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (1); PolyPhen possibly damaging (0.669); catalogued as COSV53468106; called by muse, varscan2
- PCDHA11 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.104); catalogued as rs376620715, COSV56521586; called by muse, mutect2, varscan2
- PCDHA12 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as COSV56535192; called by muse, mutect2, varscan2
- PCDHA3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as rs782257139, COSV65364473; called by muse, mutect2, varscan2
- PCDHA3 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.329); catalogued as COSV63540253; called by muse, mutect2, varscan2
- PCDHA8 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV65336069; called by muse, varscan2
- PCDHA8 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); catalogued as rs782524668, COSV65326007, COSV65329018; called by muse, mutect2, varscan2
- PCDHA9 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65324524; called by muse, mutect2, varscan2
- PCDHB13 | c.1540T>C p.F514L | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs374432821; called by muse, mutect2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2, varscan2
- PCDHGA5 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as rs753242901, COSV53976375; called by muse, mutect2, varscan2
- PCNX3 | c.5530G>A p.G1844S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1241973128, COSV63136548; called by muse, mutect2, varscan2
- PCNX4 | c.2371G>A p.A791T (on ENST00000406854 / NM_001330177.2; = p.A557T on NM_022495.5) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs762450999; called by muse, varscan2
- PDCL | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as rs1426204909; called by muse, mutect2, varscan2
- PDGFC | c.920A>C p.E307A | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99926477; called by muse, mutect2, varscan2
- PDLIM2 | c.709dup p.R237Pfs*16 (on ENST00000397760; = p.R487Pfs*16 on NM_021630.6) | Frame Shift Ins (INS) | VAF 29/99 reads (29%) | catalogued as rs1311076664; called by mutect2, pindel, varscan2
- PDLIM4 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs202040278, COSV99516865; called by muse, mutect2, varscan2
- PDZD7 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960082454; called by muse, mutect2, varscan2
- PER1 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs771510158; called by mutect2, varscan2
- PER1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs139250084; called by muse, mutect2, varscan2
- PER3 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1434864039; called by muse, mutect2
- PFKL | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs749065369, COSV62465098; called by muse, mutect2, varscan2
- PGAP6 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs754371790; called by mutect2, varscan2
- PGBD2 | c.1328C>T p.T443M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs773175771; called by muse, mutect2, varscan2
- PHACTR3 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs771889356, COSV63025359; called by muse, mutect2, varscan2
- PHF21B | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755715084; called by muse, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHTF2 | c.1709del p.L570Cfs*4 (on ENST00000248550 / NM_001366089.1; = p.L532Cfs*4 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as rs775426168; called by mutect2, varscan2
- PID1 | c.499G>A p.A167T (on ENST00000354069 / NM_001330156.1; = p.A165T on NM_017933.5) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.997); catalogued as rs777061648, COSV100819847; called by muse, mutect2, varscan2
- PIK3R6 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); catalogued as rs747815939; called by muse, varscan2
- PINK1 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs143620063; called by muse, varscan2
- PINK1 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779294259, COSV58630363; called by muse, mutect2, varscan2
- PIP4P2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs776367256; called by muse, varscan2
- PISD | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs537781569, COSV100338438; called by muse, mutect2, varscan2
- PJA2 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63272411; called by muse, mutect2, varscan2
- PKD1 | c.7358G>A p.R2453H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs781160268, COSV51925704; called by muse, mutect2, varscan2
- PKD1L1 | c.7879G>A p.V2627I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748971698; called by muse, mutect2, varscan2
- PLAAT3 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs981283061; called by muse, mutect2, varscan2
- PLCB3 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs142407686; called by muse, mutect2, varscan2
- PLD3 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs201893308, COSV52520064; called by muse, mutect2, varscan2
- PLEKHA4 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV99612377; called by muse, mutect2, varscan2
- PLEKHA5 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 107/148 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs770329884; called by muse, mutect2, varscan2
- PLEKHG3 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1413715719, COSV55978486; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as rs953293505; called by mutect2, varscan2
- PLXNB2 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs1220605772; called by muse, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- POLE | c.4169G>A p.R1390H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs200776293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as rs753626854; called by mutect2, varscan2
- POMGNT1 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | PolyPhen benign (0.345); catalogued as COSV100915530; called by muse, mutect2, varscan2
- PON2 | c.195dup p.S66* | Frame Shift Ins (INS) | VAF 24/57 reads (42%) | catalogued as rs1201102139; called by mutect2, varscan2
- POT1 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554423983, COSV62929238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEE | c.2759C>A p.A920D | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100388222; called by muse, mutect2, varscan2
- PPID | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs762653393, COSV100306815; called by muse, mutect2, varscan2
- PPL | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs755310125, COSV52166128; called by muse, mutect2, varscan2
- PPP1R26 | c.3161del p.G1054Afs*100 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs1554733377; called by mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs758484975; called by mutect2, varscan2
- PPP6R2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781275207; called by muse, mutect2, varscan2
- PREX2 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs750933833, COSV55778622; called by muse, mutect2, varscan2
- PRKCZ | c.1669G>A p.V557M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1040209932; called by muse, mutect2, varscan2
- PRKD2 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs771555628; called by muse, mutect2, varscan2
- PRM3 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs575572091; called by muse, mutect2, varscan2
- PROKR1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as rs746208336, COSV100375804; called by muse, mutect2, varscan2
- PROM2 | c.1580del p.P527Rfs*3 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as COSV58301311; called by mutect2, pindel, varscan2
- PROSER1 | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV61487001; called by muse, mutect2, varscan2
- PRSS36 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as COSV99191300; called by muse, mutect2, varscan2
- PRSS8 | c.124del p.Q42Kfs*64 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as COSV99571515; called by mutect2, varscan2
- PTCHD3 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs781287428; called by muse, mutect2, varscan2
- PTCHD3 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as COSV71256297; called by muse, mutect2
- PTH1R | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as rs199627585; called by muse, mutect2, varscan2
- PTK2 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV61784304, COSV61788929; called by muse, varscan2
- PTPN1 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs367996563, COSV50395293; called by muse, mutect2, varscan2
- PTPRE | c.1915A>G p.T639A | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.375); catalogued as rs1190286306; called by muse, mutect2, varscan2
- PTPRT | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1243176969; called by muse, mutect2, varscan2
- PTPRU | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100113592; called by muse, mutect2, varscan2
- PTRHD1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs749950003, COSV53230704; called by muse, mutect2, varscan2
- PXDNL | c.2863C>A p.L955M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62488469; called by muse, mutect2, varscan2
- PXDNL | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV62478535; called by muse, mutect2, varscan2
- PXK | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371339749; called by muse, mutect2, varscan2
- PYGL | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1053584523, COSV53584685; called by muse, mutect2, varscan2
- PYGM | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV51217781; called by muse, mutect2, varscan2
- PYGO2 | c.405del p.F136Sfs*25 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as COSV100868881; called by mutect2, varscan2
- QRFPR | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751553958, COSV57677217; called by muse, mutect2, varscan2
- QRFPR | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV57677312; called by muse, mutect2, varscan2
- RAB11FIP5 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as rs912737985, COSV50256691; called by muse, mutect2, varscan2
- RAB36 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs776616565; called by muse, mutect2, varscan2
- RABGAP1 | c.3179C>T p.A1060V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV65379594; called by muse, mutect2, varscan2
- RANBP6 | c.2918del p.N973Mfs*12 | Frame Shift Del (DEL) | VAF 26/53 reads (49%) | catalogued as rs746880803; called by mutect2, varscan2
- RAPGEF1 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100940600, COSV64700098; called by muse, mutect2, varscan2
- RASSF2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1329141746, COSV65082276; called by muse, mutect2, varscan2
- RAVER1 | c.906del p.G303Afs*232 (on ENST00000615032; = p.G303Afs*204 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as COSV99532233; called by mutect2, pindel, varscan2
- RB1 | c.287del p.K96Rfs*15 | Frame Shift Del (DEL) | VAF 51/110 reads (46%) | catalogued as CM061928, COSV57318349; called by mutect2, pindel, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM46 | c.1442del p.P481Lfs*68 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as COSV55980222; called by mutect2, pindel, varscan2
- RBM47 | c.1495G>A p.A499T (on ENST00000295971 / NM_001098634.2; = p.A430T on NM_019027.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs756413413; called by muse, mutect2, varscan2
- RBM6 | c.293dup p.D99Rfs*6 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | catalogued as rs764709206; called by mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as COSV56484832; called by mutect2, varscan2
- RCBTB2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.75); catalogued as rs371016980, COSV60649102; called by muse, mutect2, varscan2
- RDH13 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs764452687; called by muse, mutect2, varscan2
- REN | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs527291298, COSV65818318; called by muse, mutect2, varscan2
- RENBP | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371194237; called by muse, mutect2, varscan2
- RFX2 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs759734629; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs751982308; called by mutect2, varscan2
- RGS3 | c.1568G>A p.G523E (on ENST00000350696 / NM_001282923.2; = p.G411E on NM_017790.4) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1041033965; called by muse, mutect2, varscan2
- RIMBP2 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as rs370980032; called by muse, mutect2, varscan2
- RNASEH2B | c.925del p.I309Lfs*26 | Frame Shift Del (DEL) | VAF 35/66 reads (53%) | catalogued as rs75254367; ClinVar: benign / likely benign; called by mutect2, varscan2
- RNF114 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54868658; called by muse, mutect2, varscan2
- RNF128 | c.872G>T p.R291L (on ENST00000255499 / NM_194463.2; = p.R265L on NM_024539.3) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55248908; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO2 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773112305, COSV59894379, COSV59912142; called by muse, mutect2, varscan2
- RP1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV55111092; called by muse, mutect2, varscan2
- RPA1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54607170; called by muse, mutect2, varscan2
- RPH3A | c.1261C>T p.P421S (on ENST00000389385 / NM_001143854.2; = p.P417S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs751028142; called by muse, varscan2
- RPL10A | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs1309265705; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPP40 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs765129337, COSV60293110; called by muse, mutect2, varscan2
- RPUSD4 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs765735907, COSV100028563; called by muse, mutect2, varscan2
- RTCB | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs895945236; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | catalogued as rs747510098; called by mutect2, varscan2
- RTN4IP1 | c.194T>C p.M65T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs369908058; called by muse, mutect2, varscan2
- RWDD4 | c.204del p.F68Lfs*9 | Frame Shift Del (DEL) | VAF 46/145 reads (32%) | catalogued as rs1325913157; called by mutect2, pindel, varscan2
- RXFP3 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs376877208; called by muse, mutect2, varscan2
- RYR2 | c.3025C>T p.R1009W | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368040638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL3 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468331873, COSV73306627; called by muse, mutect2, varscan2
- SAP30BP | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as rs762162999, COSV99502708; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs765867975; called by mutect2, varscan2
- SCAP | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs981916393; called by muse, mutect2, varscan2
- SCARA3 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs200594740, COSV57271639; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SCRN2 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs374214556; called by muse, mutect2, varscan2
- SEMA5B | c.2677G>A p.V893M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); catalogued as rs779789464, COSV52091775; called by muse, mutect2, varscan2
- SEPHS2 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101529310; called by muse, mutect2, varscan2
- SEPTIN11 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as rs774260132, COSV53583902; called by muse, mutect2, varscan2
- SERPINB2 | c.503del p.K168Rfs*23 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs754046467; called by mutect2, pindel, varscan2
- SF3B2 | c.2625del p.K875Nfs*59 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs759211171; called by mutect2, varscan2
- SHC4 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1259320946, COSV60109362; called by muse, mutect2, varscan2
- SHROOM2 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as rs767849094; called by muse, varscan2
- SIGLEC1 | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as rs376260161; called by muse, mutect2, varscan2
- SLC11A2 | c.782G>A p.S261N (on ENST00000394904 / NM_001379455.1; = p.S232N on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100014729; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC19A1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs759645172, COSV60756388; called by muse, mutect2, varscan2
- SLC20A2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs140978915; called by muse, mutect2, varscan2
- SLC25A23 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs549386407, COSV51194334; called by muse, mutect2, varscan2
- SLC26A1 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374288131; called by muse, mutect2, varscan2
- SLC26A2 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.873); catalogued as rs1255823894; called by muse, mutect2, varscan2
- SLC29A1 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs1364039388, COSV57577131; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 20/26 reads (77%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC44A2 | c.1107_1109del p.F369del | In Frame Del (DEL) | VAF 67/133 reads (50%) | catalogued as rs768707304; called by pindel, varscan2
- SLC44A4 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs745490493, COSV57666350; called by muse, mutect2, varscan2
- SLC5A8 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV101610574, COSV73310669; called by muse, mutect2, varscan2
- SLC6A13 | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58260541; called by muse, mutect2, varscan2
- SLC7A7 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1566439001; called by mutect2, varscan2
- SLC9A2 | c.2243del p.P748Qfs*34 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs748701652; called by mutect2, pindel, varscan2
- SLC9C1 | c.29del p.F10Sfs*11 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs749004401; called by mutect2, varscan2
- SLCO3A1 | c.1654A>G p.M552V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.089); catalogued as COSV59236733; called by muse, mutect2, varscan2
- SLFN13 | c.2446G>A p.V816M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs768569837, COSV53192310; called by muse, mutect2, varscan2
- SLITRK3 | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV53849448; called by muse, mutect2, varscan2
- SLITRK5 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs113077003; called by muse, mutect2, varscan2
- SMARCA4 | c.3480del p.L1161Sfs*3 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as COSV60788830, COSV60801962; called by mutect2, pindel, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | catalogued as rs754697669; called by mutect2, varscan2
- SMG7 | c.2687G>A p.R896Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.147); catalogued as rs778241737; called by muse, mutect2, varscan2
- SNAP47 | c.491del p.G164Afs*4 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as COSV100248148; called by mutect2, pindel, varscan2
- SNCG | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs371074090; called by muse, mutect2, varscan2
- SNED1 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs1026206217; called by muse, mutect2, varscan2
- SNRNP35 | c.443del p.K148Rfs*6 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as rs1566105559; called by mutect2, pindel, varscan2
- SNTB2 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 51/76 reads (67%) | catalogued as rs781675839, COSV60351915; called by muse, mutect2, varscan2
- SNTG1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52441689; called by muse, mutect2, varscan2
- SNX1 | c.1221+1G>A p.X407_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as rs1567331657, COSV56038002; called by muse, mutect2, varscan2
- SNX25 | c.1698C>T p.C566= | Splice Region (SNP) | VAF 33/88 reads (38%) | catalogued as rs759992210, COSV53011566; called by muse, mutect2, varscan2
- SNX32 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs562049246; called by muse, mutect2, varscan2
- SOCS3 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458431134, COSV58271351; called by muse, mutect2, varscan2
- SORBS2 | c.25T>C p.S9P (on ENST00000284776 / NM_021069.5; = p.S55P on NM_003603.6) | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs757565438; called by muse, mutect2, varscan2
- SPATA13 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV57980782; called by muse, mutect2, varscan2
- SPECC1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs764238558, COSV54960010; called by muse, mutect2, varscan2
- SPEF2 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770811953, COSV56798790; called by muse, mutect2, varscan2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs752907815; called by mutect2, pindel, varscan2
- SPEM1 | c.859del p.L287* | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as COSV57210262; called by mutect2, pindel, varscan2
- SPOCK1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs151283855; called by muse, mutect2, varscan2
1,225 further variants in this file (776 protein-altering or splice-affecting, 413 silent, 36 other) are not listed here.
